Somatic mutation profile of tumor specimen TCGA-06-5417-01A (aliquot TCGA-06-5417-01A-01D-1486-08) from TCGA case TCGA-06-5417, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 45.4 years (16,572 days).
Specimen TCGA-06-5417-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba9df793-e457-4e13-990a-f54ef6e21d73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-5417-10A (Blood Derived Normal), aliquot TCGA-06-5417-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfb8bb92-e443-4e2b-b8ee-3d3de0c2e019

The open-access MAF lists 61 somatic variants for this specimen: 45 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 15, Frame Shift Del 5, Nonsense Mutation 2, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 48/120 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 45/93 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.764T>G p.I255S | Missense Mutation (SNP) | VAF 46/80 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs876659675, COSV52685038, COSV52712740, COSV52714133; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 46/85 reads (54%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACOT12 | c.631A>G p.T211A | Missense Mutation (SNP) | VAF 257/527 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV56894042; called by muse, mutect2, varscan2
- ATRX | c.6761A>G p.H2254R | Missense Mutation (SNP) | VAF 191/364 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM092484, COSV64874045; called by muse, mutect2, varscan2
- BUD13 | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs772347423, COSV52767721; called by muse, mutect2, varscan2
- CFAP47 | c.1705C>T p.R569C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs924461410, COSV52882650; called by muse, mutect2, varscan2
- CTTNBP2 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 239/410 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.092); catalogued as COSV50393413; called by muse, mutect2, varscan2
- EFHC2 | c.1814G>T p.R605L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59092864; called by muse, mutect2, varscan2
- EFR3A | c.532A>G p.K178E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54455291; called by muse, mutect2
- EIF4G1 | c.4755C>G p.F1585L (on ENST00000346169 / NM_198241.3; = p.F1390L on NM_004953.5) | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59990004; called by muse, mutect2, varscan2
- GEMIN8 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60550291; called by muse, mutect2, varscan2
- GRHL3 | c.205G>T p.G69C (on ENST00000350501 / NM_198174.3; = p.G74C on NM_021180.3) | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV52565459; called by muse, mutect2
- GUCY2F | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 150/254 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54300197; called by muse, mutect2, varscan2
- HDX | c.636del p.K212Nfs*105 | Frame Shift Del (DEL) | VAF 101/335 reads (30%) | catalogued as COSV52979506; called by mutect2, pindel, varscan2
- KCNA10 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 106/197 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754042866, COSV63904449; called by muse, mutect2, varscan2
- LACTB | c.1403A>G p.E468G | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV56055612; called by muse, mutect2, varscan2
- LAS1L | c.1853C>A p.P618H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.361); catalogued as COSV56706793; called by muse, mutect2, varscan2
- NR2C1 | c.1051C>A p.H351N | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV58009162; called by muse, mutect2, varscan2
- OR13C8 | c.848T>C p.F283S | Missense Mutation (SNP) | VAF 20/233 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.968); catalogued as COSV58610804; called by muse, mutect2
- OR4S1 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 129/270 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377193891; called by muse, mutect2, varscan2
- PANX2 | c.738C>A p.C246* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV50293118; called by muse, mutect2, varscan2
- PLEKHG6 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 52/67 reads (78%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV50599211; called by muse, mutect2, varscan2
- POLQ | c.1601C>G p.A534G | Missense Mutation (SNP) | VAF 24/267 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV51748850; called by muse, mutect2
- POLR2B | c.2924G>A p.R975H | Missense Mutation (SNP) | VAF 190/310 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58899541; called by muse, mutect2, varscan2
- PPL | c.410A>G p.N137S | Missense Mutation (SNP) | VAF 67/106 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV62045860; called by muse, varscan2
- RPS6KC1 | c.1718T>C p.F573S | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as COSV65298213; called by muse, mutect2, varscan2
- RYR3 | c.13430G>T p.R4477L (on ENST00000389232; = p.R4478L on NM_001036.6) | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV104430568, COSV66783133; called by muse, mutect2, varscan2
- SOX4 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55192986; called by muse, mutect2, varscan2
- SPTBN1 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 97/229 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61687051; called by muse, mutect2, varscan2
- TUT1 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV53469390; called by muse, mutect2, varscan2
- VARS2 | c.2948A>G p.Y983C | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs767732680, COSV58911825; called by muse, mutect2, varscan2
- WDR19 | c.1260A>T p.K420N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.32); catalogued as COSV56463409; called by muse, mutect2
- XKR9 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 170/382 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68772724; called by muse, mutect2, varscan2
- ZAR1 | c.996C>G p.C332W | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51943790; called by muse, mutect2
- ZMYM3 | c.1409T>C p.L470P | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV58736972; called by muse, mutect2, varscan2
- ZNF544 | c.673A>C p.S225R | Missense Mutation (SNP) | VAF 103/112 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV54135112; called by muse, mutect2, varscan2
- ZNF674 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV70378782; called by muse, mutect2, varscan2
- CDK12 | c.397dup p.S133Kfs*24 | Frame Shift Ins (INS) | VAF 43/106 reads (41%) | called by mutect2, pindel, varscan2
- EPAS1 | c.1096del p.H366Tfs*2 | Frame Shift Del (DEL) | VAF 141/534 reads (26%) | called by mutect2, pindel, varscan2
- LRP1 | c.3163+1del | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel
- OGA | c.1387_1389del p.E463del | In Frame Del (DEL) | VAF 206/502 reads (41%) | called by pindel, varscan2
- ROBO1 | c.4557_4560del p.R1520Hfs*102 | Frame Shift Del (DEL) | VAF 188/522 reads (36%) | called by pindel, varscan2
- WWC2 | c.3170del p.T1057Kfs*11 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- BAIAP3 | c.915G>A p.A305= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as rs373003886; called by muse, mutect2, varscan2
- COL4A5 | c.1773A>G p.G591= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as COSV60358914; called by muse, mutect2, varscan2
- ELK3 | c.354C>T p.G118= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV57386058; called by muse, mutect2, varscan2
- FLG2 | c.4161A>G p.R1387= | Silent (SNP) | VAF 154/496 reads (31%) | catalogued as COSV66167578; called by muse, mutect2, varscan2
- GZMB | c.168C>T p.D56= | Silent (SNP) | VAF 58/123 reads (47%) | catalogued as rs766574069, COSV53540773; called by muse, mutect2
- LMBRD1 | c.987C>G p.V329= (on ENST00000649011; = p.V307= on NM_018368.4) | Silent (SNP) | VAF 48/106 reads (45%) | catalogued as COSV65296721; called by muse, mutect2, varscan2
- LRRIQ1 | c.1950T>C p.A650= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV67828202; called by muse, mutect2, varscan2
- MDH1B | c.921C>T p.D307= | Silent (SNP) | VAF 70/188 reads (37%) | catalogued as rs146327472, COSV65590806; called by muse, mutect2, varscan2
- MIGA1 | c.1656G>C p.L552= | Silent (SNP) | VAF 102/265 reads (38%) | catalogued as COSV66223262; called by muse, mutect2, varscan2
- POLDIP2 | c.1041G>T p.R347= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV50228274; called by muse, mutect2, varscan2
- SEL1L3 | c.1545G>A p.L515= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs764219010, COSV53538358; called by muse, mutect2, varscan2
- STARD4 | c.150A>C p.G50= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV56967641; called by muse, mutect2, varscan2
- STARD8 | c.2730C>G p.V910= | Silent (SNP) | VAF 2/9 reads (22%) | catalogued as COSV52923789; called by muse, mutect2
- SYNE1 | c.6003T>C p.T2001= (on ENST00000367255 / NM_182961.4; = p.T2008= on NM_033071.3) | Silent (SNP) | VAF 250/568 reads (44%) | catalogued as COSV54944202; called by muse, mutect2, varscan2
- TTLL7 | c.513T>A p.S171= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV53082944; called by muse, mutect2, varscan2
- COLCA2 | chr11:111296113 A>G | 5'Flank (SNP) | VAF 91/188 reads (48%) | called by muse, mutect2, varscan2
